Somatic mutation profile of tumor specimen TCGA-85-8479-01A (aliquot TCGA-85-8479-01A-11D-2323-08) from TCGA case TCGA-85-8479, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary squamous cell carcinoma; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 66.7 years (24,350 days).
Specimen TCGA-85-8479-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 881cab3e-c794-4513-919e-eb0f9bbdf6aa.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-85-8479-10A (Blood Derived Normal), aliquot TCGA-85-8479-10A-01D-2323-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3b96d6ce-5667-4922-bca9-ae6cf720842e

The open-access MAF lists 130 somatic variants for this specimen: 90 protein-altering or splice-affecting, 36 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 77, Silent 36, Nonsense Mutation 6, Intron 2, Splice Region 2, Frame Shift Del 2, In Frame Del 1, Splice Site 1, Frame Shift Ins 1, 5'UTR 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.375G>T p.T125= | Splice Region (SNP) | VAF 36/72 reads (50%) | catalogued as rs55863639, CS004351, CS011573, CS971913, COSV52665709, COSV52718605, COSV52726641, COSV53120615; ClinVar: not provided / likely pathogenic; called by muse, mutect2, varscan2
- ABCC6 | c.3913A>T p.K1305* | Nonsense Mutation (SNP) | VAF 6/14 reads (43%) | catalogued as COSV99229347; called by muse, varscan2
- ACTR3 | c.698A>T p.Y233F | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.412); catalogued as COSV99603880; called by muse, mutect2, varscan2
- ADGRL3 | c.2716C>G p.R906G (on ENST00000506720 / NM_001322402.2; = p.R838G on NM_015236.6) | Missense Mutation (SNP) | VAF 12/20 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV101547330, COSV72229448; called by muse, mutect2, varscan2
- AL121899.2 | c.1147G>T p.V383L | Missense Mutation (SNP) | VAF 35/117 reads (30%) | SIFT tolerated (0.48); PolyPhen benign (0.003); catalogued as COSV101198607; called by muse, mutect2, varscan2
- ANKRD35 | c.1046C>T p.S349F | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT tolerated (0.36); PolyPhen benign (0.019); catalogued as COSV100841821; called by muse, mutect2, varscan2
- ANO5 | c.1891A>G p.I631V | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT tolerated (0.71); PolyPhen benign (0.034); catalogued as COSV100202074; called by muse, mutect2, varscan2
- ANPEP | c.355G>A p.V119I | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.014); catalogued as rs370969705; called by muse, mutect2, varscan2
- APBA2 | c.499A>G p.I167V | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT tolerated, low confidence (0.6); PolyPhen benign (0); catalogued as COSV101382468; called by muse, mutect2, varscan2
- ARHGAP19 | c.514C>T p.H172Y | Missense Mutation (SNP) | VAF 38/105 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as COSV100363282; called by muse, mutect2, varscan2
- ASL | c.94C>T p.R32W | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.02); catalogued as rs901715532, COSV100508968; called by muse, mutect2, varscan2
- CD163 | c.3223C>T p.R1075* | Nonsense Mutation (SNP) | VAF 70/195 reads (36%) | catalogued as COSV63138480; called by muse, mutect2, varscan2
- CD40LG | c.487G>A p.V163I | Missense Mutation (SNP) | VAF 76/298 reads (26%) | SIFT tolerated (0.31); PolyPhen benign (0.039); catalogued as rs199914973, COSV65698365; ClinVar: benign; called by muse, mutect2, varscan2
- CDHR2 | c.3634A>G p.N1212D | Missense Mutation (SNP) | VAF 20/76 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.594); catalogued as COSV99992020; called by muse, mutect2, varscan2
- CDK8 | c.963A>G p.I321M | Missense Mutation (SNP) | VAF 56/134 reads (42%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.56); catalogued as COSV101037472; called by muse, mutect2, varscan2
- CLPB | c.717G>T p.W239C | Missense Mutation (SNP) | VAF 40/89 reads (45%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.417); catalogued as rs904417160, COSV53633880; called by muse, mutect2, varscan2
- CLPS | c.55C>T p.P19S | Missense Mutation (SNP) | VAF 42/175 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs1267702100, COSV99463877; called by muse, mutect2, varscan2
- CNGB1 | c.3535G>T p.A1179S | Missense Mutation (SNP) | VAF 18/79 reads (23%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV99206253; called by muse, mutect2, varscan2
- CNTN6 | c.2731G>T p.A911S | Missense Mutation (SNP) | VAF 24/37 reads (65%) | SIFT tolerated (0.67); PolyPhen probably damaging (0.985); catalogued as COSV100611561; called by muse, mutect2, varscan2
- CPSF1 | c.263G>T p.G88V | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.441); catalogued as COSV100574711; called by muse, mutect2, varscan2
- CRHR1 | c.135C>A p.N45K | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.745); catalogued as COSV53276123, COSV99523984; called by muse, mutect2, varscan2
- CYP4F8 | c.136C>T p.R46C | Missense Mutation (SNP) | VAF 45/198 reads (23%) | SIFT tolerated (0.27); PolyPhen benign (0.022); catalogued as rs777640566, COSV100358195; called by muse, mutect2, varscan2
- DBF4 | c.1595G>A p.G532D | Missense Mutation (SNP) | VAF 30/104 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99719525; called by muse, mutect2, varscan2
- DCAF4L2 | c.1003G>C p.D335H | Missense Mutation (SNP) | VAF 39/110 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100151173, COSV60476583; called by muse, mutect2, varscan2
- DEPTOR | c.120A>G p.L40= | Splice Region (SNP) | VAF 9/68 reads (13%) | catalogued as COSV99639127; called by muse, mutect2, varscan2
- DHRS7C | c.103G>T p.V35L | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT tolerated (0.63); PolyPhen benign (0.052); catalogued as COSV100364851; called by muse, mutect2, varscan2
- DRD3 | c.244G>T p.V82L | Missense Mutation (SNP) | VAF 55/152 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); catalogued as COSV99879612; called by muse, mutect2, varscan2
- ERICH3 | c.1997A>C p.E666A | Missense Mutation (SNP) | VAF 57/155 reads (37%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.492); catalogued as COSV58617224; called by muse, mutect2, varscan2
- FAM8A1 | c.1141T>C p.F381L | Missense Mutation (SNP) | VAF 12/138 reads (9%) | SIFT tolerated (0.27); PolyPhen benign (0.109); catalogued as COSV52583226, COSV99467871; called by muse, mutect2
- FAT1 | c.394C>T p.R132* | Nonsense Mutation (SNP) | VAF 65/127 reads (51%) | catalogued as COSV101499290, COSV71671964; called by muse, mutect2, varscan2
- FBN1 | c.7970C>A p.A2657D | Missense Mutation (SNP) | VAF 25/117 reads (21%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.998); catalogued as COSV100356047; called by muse, mutect2, varscan2
- FOXD4L3 | c.1046G>T p.R349L | Missense Mutation (SNP) | VAF 68/173 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs782316489, COSV100731025, COSV61551455; called by muse, mutect2, varscan2
- GCNT1 | c.1178G>A p.R393H | Missense Mutation (SNP) | VAF 80/134 reads (60%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs201887404, COSV65056972; called by muse, mutect2, varscan2
- HIVEP3 | c.5269G>A p.E1757K | Missense Mutation (SNP) | VAF 28/129 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.913); catalogued as COSV99913564; called by muse, mutect2, varscan2
- IFT88 | c.1550A>T p.K517I (on ENST00000319980 / NM_001318493.2; = p.K508I on NM_006531.5 and 9 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 38/69 reads (55%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.9); catalogued as COSV100179831; called by muse, mutect2, varscan2
- ITGB8 | c.1856G>A p.S619N | Missense Mutation (SNP) | VAF 39/104 reads (38%) | SIFT tolerated (0.25); PolyPhen benign (0.196); catalogued as rs1355542860, COSV99752069; called by muse, mutect2, varscan2
- ITPR3 | c.5167G>A p.A1723T | Missense Mutation (SNP) | VAF 44/148 reads (30%) | SIFT tolerated (0.28); PolyPhen benign (0.08); catalogued as COSV100967867; called by muse, mutect2, varscan2
- KCNJ12 | c.655C>T p.R219C | Missense Mutation (SNP) | VAF 16/30 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs373903627; called by muse, mutect2, varscan2
- KCTD8 | c.1174C>T p.P392S | Missense Mutation (SNP) | VAF 80/237 reads (34%) | SIFT tolerated (0.25); PolyPhen benign (0.297); catalogued as COSV100759921; called by muse, mutect2, varscan2
- LHX5 | c.565G>A p.A189T | Missense Mutation (SNP) | VAF 25/48 reads (52%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.897); catalogued as COSV99922536; called by muse, mutect2, varscan2
- LIPH | c.823G>A p.D275N | Missense Mutation (SNP) | VAF 54/230 reads (23%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.582); catalogued as COSV99956235; called by muse, mutect2, varscan2
- LTBP4 | c.1799C>T p.P600L (on ENST00000308370 / NM_001042544.1; = p.P563L on NM_003573.2) | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.723); catalogued as COSV99199099; called by muse, mutect2, varscan2
- MAMSTR | c.1178G>A p.S393N (on ENST00000318083 / NM_001130915.2; = p.S290N on NM_182574.2) | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV100540621; called by muse, mutect2, varscan2
- MUC16 | c.8011G>A p.V2671M | Missense Mutation (SNP) | VAF 43/93 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.934); catalogued as COSV101200763; called by muse, mutect2, varscan2
- MUC16 | c.2161A>T p.S721C | Missense Mutation (SNP) | VAF 23/150 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.623); catalogued as COSV101200767; called by muse, mutect2, varscan2
- MVB12B | c.496A>T p.M166L | Missense Mutation (SNP) | VAF 99/150 reads (66%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100753069; called by muse, mutect2, varscan2
- MYH3 | c.4307C>A p.A1436D | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.864); catalogued as COSV99878647; called by muse, mutect2, varscan2
- NEB | c.17333C>G p.P5778R | Missense Mutation (SNP) | VAF 21/89 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99426262; called by muse, mutect2, varscan2
- OBI1 | c.1858C>T p.Q620* | Nonsense Mutation (SNP) | VAF 7/177 reads (4%) | catalogued as rs1413837096, COSV99932584, COSV99932727; called by muse, mutect2
- OLFM3 | c.1018A>G p.T340A (on ENST00000338858 / NM_001288821.1; = p.T320A on NM_058170.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT tolerated (0.2); PolyPhen benign (0.194); catalogued as COSV58803823; called by muse, mutect2, varscan2
- OR11H12 | c.967T>C p.S323P | Missense Mutation (SNP) | VAF 57/93 reads (61%) | SIFT tolerated (0.27); PolyPhen benign (0.005); catalogued as COSV101612515; called by muse, mutect2, varscan2
- OR14K1 | c.547C>G p.L183V | Missense Mutation (SNP) | VAF 106/283 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.784); catalogued as COSV99315382; called by muse, mutect2, varscan2
- PCDHA2 | c.1684G>A p.A562T | Missense Mutation (SNP) | VAF 64/216 reads (30%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.082); catalogued as rs782465720, COSV65368209; called by muse, mutect2, varscan2
- PDIA4 | c.1393G>T p.D465Y (on ENST00000286091 / NM_001371244.1; = p.D464Y on NM_004911.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 58/207 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.069); catalogued as COSV99618786; called by muse, mutect2, varscan2
- PDIA4 | c.1392G>T p.K464N (on ENST00000286091 / NM_001371244.1; = p.K463N on NM_004911.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 57/206 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV99618792; called by muse, mutect2, varscan2
- PLCB4 | c.968T>C p.F323S | Missense Mutation (SNP) | VAF 40/115 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as COSV99596471; called by muse, mutect2, varscan2
- PLEC | c.7169C>T p.A2390V (on ENST00000322810 / NM_201380.4; = p.A2280V on NM_000445.5) | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.026); catalogued as rs782329522, COSV100517474; ClinVar: uncertain significance; called by mutect2, varscan2
- POU3F3 | c.1348G>T p.V450L | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV100796874; called by muse, mutect2, varscan2
- PPEF1 | c.1557C>A p.N519K | Missense Mutation (SNP) | VAF 110/147 reads (75%) | SIFT tolerated (0.13); PolyPhen benign (0.005); catalogued as COSV100583974; called by muse, mutect2, varscan2
- PRDM9 | c.1750G>T p.E584* | Nonsense Mutation (SNP) | VAF 42/210 reads (20%) | catalogued as COSV99690946; called by muse, mutect2, varscan2
- PRSS37 | c.440C>T p.P147L | Missense Mutation (SNP) | VAF 25/88 reads (28%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.995); catalogued as COSV100633896; called by muse, mutect2, varscan2
- PTBP3 | c.1099C>T p.P367S | Missense Mutation (SNP) | VAF 37/52 reads (71%) | SIFT tolerated (0.08); PolyPhen benign (0.284); catalogued as rs373393745; called by muse, mutect2, varscan2
- PTPRK | c.793C>T p.Q265* | Nonsense Mutation (SNP) | VAF 52/112 reads (46%) | catalogued as COSV100949676; called by muse, mutect2, varscan2
- RALBP1 | c.1852G>A p.V618I | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0); catalogued as rs772113798, COSV50034911; called by muse, mutect2, varscan2
- RANBP2 | c.2713A>G p.M905V | Missense Mutation (SNP) | VAF 28/80 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.023); catalogued as COSV99312896; called by muse, mutect2, varscan2
- RAPGEF1 | c.1073G>T p.S358I | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.959); catalogued as COSV100940691, COSV64701338; called by muse, mutect2, varscan2
- RIPK4 | c.440C>T p.A147V | Missense Mutation (SNP) | VAF 25/41 reads (61%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs746468215, COSV60192489; called by muse, mutect2, varscan2
- RNASE7 | c.97A>T p.M33L | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT tolerated (0.88); PolyPhen benign (0); catalogued as COSV100069740; called by muse, mutect2, varscan2
- SLC50A1 | c.521C>T p.S174F | Missense Mutation (SNP) | VAF 30/131 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.593); catalogued as COSV100310178, COSV100310460; called by muse, mutect2, varscan2
- SMC5 | c.1622C>T p.P541L | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100747145; called by muse, mutect2, varscan2
- SNX1 | c.970C>T p.R324W | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs146206725; called by muse, mutect2, varscan2
- SPEF2 | c.4873C>A p.Q1625K | Missense Mutation (SNP) | VAF 153/357 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.023); catalogued as COSV100289295; called by muse, mutect2, varscan2
- SRGAP3 | c.1990A>G p.M664V | Missense Mutation (SNP) | VAF 57/88 reads (65%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.72); catalogued as COSV100841285; called by muse, mutect2, varscan2
- TMEM132E | c.1925C>G p.S642C (on ENST00000321639; = p.S732C on NM_001304438.2) | Missense Mutation (SNP) | VAF 47/92 reads (51%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.54); catalogued as COSV100396661; called by muse, mutect2, varscan2
- TMEM255B | c.964C>T p.P322S | Missense Mutation (SNP) | VAF 69/306 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs747458917, COSV100944145; called by muse, mutect2, varscan2
- TRABD | c.331C>T p.R111C | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1362400681, COSV57713685; called by muse, mutect2, varscan2
- TRIM46 | c.808C>A p.L270I | Missense Mutation (SNP) | VAF 99/209 reads (47%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.841); catalogued as COSV99826048; called by muse, mutect2, varscan2
- UNC13C | c.3957G>T p.L1319F | Missense Mutation (SNP) | VAF 16/222 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV52909443, COSV99521507; called by muse, mutect2
- VPS13A | c.7435A>G p.I2479V | Missense Mutation (SNP) | VAF 29/38 reads (76%) | SIFT tolerated (0.61); PolyPhen benign (0.084); catalogued as rs200991231; called by muse, mutect2, varscan2
- ZC3H6 | c.250A>T p.S84C | Missense Mutation (SNP) | VAF 24/102 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV100674791; called by muse, mutect2, varscan2
- ZNF70 | c.1208G>T p.R403L | Missense Mutation (SNP) | VAF 77/215 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0.289); catalogued as COSV100558923, COSV59532795; called by muse, mutect2, varscan2
- ZNF91 | c.2404G>A p.E802K | Missense Mutation (SNP) | VAF 52/108 reads (48%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV100323306; called by muse, mutect2, varscan2
- ADGRB2 | c.3018_3020del p.F1007del | In Frame Del (DEL) | VAF 8/42 reads (19%) | called by pindel, varscan2
- ANKAR | c.1088G>A p.R363K | Missense Mutation (SNP) | VAF 3/40 reads (8%) | SIFT tolerated (0.83); PolyPhen benign (0); called by muse, mutect2
- ATN1 | c.2849_2862del p.F950* | Frame Shift Del (DEL) | VAF 36/136 reads (26%) | called by mutect2, pindel, varscan2
- CCDC120 | c.1045del p.S349Pfs*4 | Frame Shift Del (DEL) | VAF 30/54 reads (56%) | called by mutect2, pindel, varscan2
- MYOM3 | c.3424G>A p.V1142M | Missense Mutation (SNP) | VAF 35/94 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.428); called by mutect2, varscan2
- NBPF26 | c.4104-2A>C p.X1368_splice (on ENST00000620612; = p.X1106_splice on NM_001351372.1) | Splice Site (SNP) | VAF 70/222 reads (32%) | called by muse, varscan2
- PBRM1 | c.2973dup p.W992Mfs*12 | Frame Shift Ins (INS) | VAF 12/39 reads (31%) | called by mutect2, pindel, varscan2
- SSU72P8 | c.386A>G p.Q129R | Missense Mutation (SNP) | VAF 25/74 reads (34%) | SIFT tolerated (0.14); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- ACOX3 | c.312C>T p.P104= | Silent (SNP) | VAF 31/103 reads (30%) | catalogued as rs754191819, COSV100712030, COSV62713695; called by muse, mutect2, varscan2
- ACVRL1 | c.492G>A p.L164= | Silent (SNP) | VAF 21/56 reads (38%) | catalogued as COSV101188059; called by muse, mutect2, varscan2
- ADAM10 | c.702A>G p.K234= | Silent (SNP) | VAF 19/47 reads (40%) | catalogued as COSV99546462; called by muse, mutect2, varscan2
- ANKRD30A | c.1998A>G p.R666= (on ENST00000611781; = p.R610= on NM_052997.2) | Silent (SNP) | VAF 17/51 reads (33%) | catalogued as COSV100654203; called by muse, mutect2, varscan2
- ASPHD1 | c.276C>T p.L92= | Silent (SNP) | VAF 51/201 reads (25%) | catalogued as COSV100435708, COSV58098789; called by muse, mutect2, varscan2
- ATL3 | c.1191T>C p.H397= | Silent (SNP) | VAF 35/65 reads (54%) | catalogued as COSV100219958; called by muse, mutect2, varscan2
- CLVS1 | c.927G>A p.K309= | Silent (SNP) | VAF 18/63 reads (29%) | catalogued as COSV100370443; called by muse, mutect2, varscan2
- CNR1 | c.1287G>A p.S429= | Silent (SNP) | VAF 89/199 reads (45%) | catalogued as rs149238893; called by muse, mutect2, varscan2
- DSCAM | c.1395G>A p.V465= | Silent (SNP) | VAF 36/58 reads (62%) | catalogued as COSV101261179, COSV68022729; called by muse, mutect2, varscan2
- EPAS1 | c.621T>A p.P207= | Silent (SNP) | VAF 30/101 reads (30%) | catalogued as COSV99763452; called by muse, mutect2, varscan2
- FAM155A | c.678T>C p.C226= | Silent (SNP) | VAF 74/296 reads (25%) | catalogued as COSV101029627; called by muse, mutect2, varscan2
- FBL | c.927C>T p.V309= | Silent (SNP) | VAF 29/99 reads (29%) | catalogued as COSV55682308; called by muse, mutect2, varscan2
- FIBCD1 | c.768C>T p.G256= | Silent (SNP) | VAF 84/139 reads (60%) | catalogued as rs1482462527, COSV53392963; called by muse, mutect2, varscan2
- GJB5 | c.348C>G p.L116= | Silent (SNP) | VAF 42/152 reads (28%) | catalogued as COSV100258625; called by muse, mutect2, varscan2
- GRIN2B | c.1728C>G p.V576= | Silent (SNP) | VAF 54/139 reads (39%) | catalogued as COSV101663136, COSV74207591; called by muse, mutect2, varscan2
- KMO | c.594T>C p.T198= | Silent (SNP) | VAF 72/280 reads (26%) | catalogued as rs555934198, COSV100844811; called by muse, mutect2, varscan2
- LRP1B | c.13014G>C p.G4338= | Silent (SNP) | VAF 22/57 reads (39%) | catalogued as rs895452653, COSV101259244; called by muse, mutect2, varscan2
- LY9 | c.1704G>A p.Q568= | Silent (SNP) | VAF 144/280 reads (51%) | catalogued as COSV99627239; called by muse, mutect2, varscan2
- MGAT3 | c.1197C>T p.T399= | Silent (SNP) | VAF 21/85 reads (25%) | catalogued as rs1169149919, COSV100362019; called by muse, mutect2, varscan2
- NFXL1 | c.2076C>T p.N692= | Silent (SNP) | VAF 72/226 reads (32%) | catalogued as COSV100216971; called by muse, mutect2, varscan2
- OR10V1 | c.687C>A p.I229= | Silent (SNP) | VAF 7/82 reads (9%) | catalogued as COSV99038076; called by muse, mutect2
- OR6Q1 | c.576G>C p.S192= | Silent (SNP) | VAF 57/153 reads (37%) | catalogued as rs528605468, COSV100110351, COSV56933574; called by muse, mutect2, varscan2
- PPP3R2 | c.258C>G p.G86= | Silent (SNP) | VAF 86/153 reads (56%) | catalogued as rs368922664, COSV62453547; called by muse, mutect2, varscan2
- PRLHR | c.60G>T p.P20= | Silent (SNP) | VAF 13/102 reads (13%) | catalogued as COSV99492907, COSV99492912; called by muse, mutect2, varscan2
- SGCD | c.78T>C p.I26= (on ENST00000435422 / NM_001128209.2; = p.I27= on NM_000337.5) | Silent (SNP) | VAF 40/126 reads (32%) | catalogued as COSV100550780; called by muse, mutect2, varscan2
- SKIV2L | c.2703C>T p.L901= | Silent (SNP) | VAF 38/140 reads (27%) | catalogued as rs748012447, COSV61714949; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ST8SIA2 | c.885C>A p.T295= | Silent (SNP) | VAF 5/26 reads (19%) | catalogued as COSV51568173; called by muse, varscan2
- TDRD9 | c.2698C>T p.L900= | Silent (SNP) | VAF 36/120 reads (30%) | catalogued as COSV100175478; called by muse, mutect2, varscan2
- TMEM143 | c.1233C>T p.T411= | Silent (SNP) | VAF 11/148 reads (7%) | catalogued as COSV99507469; called by muse, mutect2
- TTN | c.22356C>T p.V7452= (on ENST00000591111; = p.V6525= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 47/130 reads (36%) | catalogued as rs185860746, COSV59899486; called by muse, mutect2, varscan2
- USH2A | c.5004T>A p.G1668= | Silent (SNP) | VAF 28/127 reads (22%) | catalogued as COSV100239882, COSV56441502; called by muse, mutect2, varscan2
- VCAN | c.6321A>G p.R2107= | Silent (SNP) | VAF 13/56 reads (23%) | catalogued as COSV99426837; called by muse, mutect2, varscan2
- WEE1 | c.855A>T p.T285= | Silent (SNP) | VAF 19/40 reads (48%) | catalogued as COSV100219803; called by muse, mutect2, varscan2
- XKR9 | c.732A>T p.I244= | Silent (SNP) | VAF 15/47 reads (32%) | catalogued as COSV101281965; called by muse, mutect2, varscan2
- YIPF2 | c.240C>T p.F80= | Silent (SNP) | VAF 36/137 reads (26%) | catalogued as COSV99450273; called by muse, mutect2, varscan2
- ZBTB7B | c.1395C>T p.D465= (on ENST00000292176; = p.D499= on NM_001252406.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 45/97 reads (46%) | catalogued as rs780876345, COSV99421438; called by muse, mutect2, varscan2
- GAGE1 | c.*2T>A | 3'UTR (SNP) | VAF 54/68 reads (79%) | called by muse, mutect2, varscan2
- RIMS2 | c.177-44862C>G | Intron (SNP) | VAF 16/107 reads (15%) | called by muse, mutect2, varscan2
- SLCO1B3-SLCO1B7 | c.1866-44389A>C | Intron (SNP) | VAF 44/114 reads (39%) | catalogued as COSV101044639; called by muse, mutect2, varscan2
- SUPT20HL2 | c.-674A>C | 5'UTR (SNP) | VAF 76/95 reads (80%) | called by muse, varscan2
